Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8D8, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8D8-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Thymoma, type AB, malignant
8582/3
Thymus C37.9
9/26/13/14

Operative Procedure:
Mediastinal dissection.

Pre-Operative Diagnosis:
See below.

Post-Operative Diagnosis:
As below.

Specimen Received:
Thymus, resection

Final Pathologic Diagnosis:
Thymus, resection:
Thymoma, mixed type (AB).
The largest tumor dimension measures 6.5 cm.
Tumor microscopically invaded into adjacent adipose tissue
All resection margins are negative for tumor.
Four adjacent lymph nodes are negative for tumor.
The attached lung shows focal interstitial fibrosis.
Pathologic stage: pT2.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:
Received in a single formalin filled container and consists of a 6.5 x 6.5 x 4.5 cm spherical, well delineated mass surrounded by fat with a 4.5 x 3.2 x 0.3 cm pyramidal portion of adhered lung. The mass is encapsulated and is adhered to the lung pleura, but did not appear to invade. Two extracapsular nodules are identified, 0.1 and 0.2 cm in greatest dimension. The cut surface of the mass is pink-tan, lobulated and minimal fibrous areas. A 0.9 x 0.4 x 0.4 cm red-brown area is present within the mass, possible lymph node or residual thymus tissue. Minimal thymus tissue can be identified. The mass is not transected. Four lymph nodes are identified in the surrounding fat, ranging from 0.2 to 0.5 cm in greatest dimension.

Representative sections are submitted as follows:

- 1 capsular margin;
- 2 adhered lung to mass;
- 3 mass;
- 4 lung;
- 5 mass;
- 6 mass;
- 7 fat with separate nodule;
- 8 mass with separate nodule;

[page 2 of 2]
- 9 mass;
- 10 mass with red-brown area, possible lymph node;
- 11-12 mass;
- 13 four whole lymph nodes.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Surgical Pathology Report

Taken: DOB: Gender: M

Source: NCI Genomic Data Commons file 2ea783d5-e1e8-4ff4-81c9-19f87ef2b273 (TCGA-X7-A8D8.AE76AB23-4099-4A78-AF35-5FCBA9535D7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).